MMRF case MMRF_2579 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2d13b839-d24a-4fb4-ba7b-d357e0237ca9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.8 years (22,560 days); ISS stage: I; Days to last known disease status: 660 days (1.8 years); Days to last follow up: 660 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 141 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: First line of therapy; Days to treatment start: 143 days; Days to treatment end: 143 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1220 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 3.39 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.51 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 3 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.2 g/dL; Glucose 6.77 mmol/L.
- Day 79 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Hemoglobin 6.76 mmol/L; Leukocytes 5.6 ×10⁹/L; Platelets 417 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 6.66 mmol/L.
- Day 182 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.26 mg/dL; Immunoglobulin G 6.92 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 7.28 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 8.2 mmol/L.
- Day 260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.31 mg/dL; Immunoglobulin G 6.92 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 385: Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Glucose 4.07 mmol/L.
- Day 499 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.4 mg/dL; Immunoglobulin G 8.77 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.65 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.87 ×10⁹/L; Absolute Neutrophil 3.03 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.5 mmol/L.
- Day 660: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 9.98 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.68 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.48 ×10⁹/L; Absolute Neutrophil 3.09 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day -6: Weight: 79 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2579_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2579_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
